Gene-level copy-number profile of tumor specimen TCGA-CV-6433-01A from TCGA case TCGA-CV-6433, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 57.1 years (20,855 days).
Specimen TCGA-CV-6433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.7ca7cb50-83a7-476d-89ae-37d1f2e13c89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6433-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c42d6d1-b65c-474a-9b37-436c2c01d442

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 5,771; copy number 2: 44,145; copy number 3: 8,274; copy number 4: 45; copy number 5: 1,477; copy number 6: 51; copy number 7: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6433-01A-11D-1682-01): tumor purity 0.73, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:102,770,040–102,911,500, 3 genes (within-gene range 0–1): AL132801.1, TRAF3, RNU6-1316P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,582 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–118,713,678, 2 genes, copy number 5: PSMC1P12, AL139148.1.
- chr3:117,672,154–117,997,592, 1 gene, copy number 5 (within-gene range 2–5): AC092691.1.
- chr3:117,719,859–198,222,513, 1,474 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:31,303,212–33,994,357, 104 genes, copy number 6–7 (broad region; genes not listed).
- chr20:34,014,969–34,017,749, 1 gene, copy number 7: AL031668.1.

Autosomal genes at a single copy (total copy number 1): 3,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
